Surgical pathology report (de-identified scan), TCGA case TCGA-IA-A83W, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Cleveland Clinic, specimen TCGA-IA-A83W-01A (Primary Tumor).

[page 1 of 2]
Results

SURGICAL PATHOLOGY

Patient Info

Patient Name

Sex
Male

DOB

Results

Specimen #:

Physician:

FINAL DIAGNOSIS

RIGHT KIDNEY, EXCISION - RENAL CELL CARCINOMA, PAPILLARY TYPE, FUHRMAN
GRADE 2 OF 4 (SEE COMMENT).

- ALL MARGINS NEGATIVE FOR NEOPLASM.
- BENIGN EPITHELIAL CYST.

COMMENT

The neoplasm measures 5.5 cm in greatest dimension and is situated in the upper pole of the kidney. The tumor invades the overlying renal capsule and is present within 1 mm from the soft tissue margin, however it does not penetrate the capsule into the perirenal fat. Renal sinus invasion or angiolymphatic invasion are not identified.

Electronic signature

SPECIMEN SUBMITTED

A: RIGHT KIDNEY

CLINICAL DATA

RIGHT RENAL MASS

ICD-O-3
Carcinoma, papillary renal cell
8260h3
Site @ Kidney NOS
164.9
JSD 10/17/13

GROSS DESCRIPTION

A. Received fresh is a specimen consisting of a right kidney surrounded by an envelope of fibroadipose tissue measuring 20.0 x 13.0 x 6.5 cm and weighing 919.34 grams. A mass involves the upper portion of the kidney. On section, the tumor mass is roughly spherical and measures 5.5 cm in greatest dimension. It is composed of yellow to tan soft homogenous tissue. Foci of hemorrhage or necrosis is not present. The tumor does extend into the perirenal fat. The tumor does not invade the pelvicaliceal system or renal sinus. The tumor is sharply demarcated from the renal parenchyma which appears essentially unremarkable. Satellite nodules of tumor are not present. Dissection of the renal veins particularly those draining the area of the mass does not show the intravascular present of a neoplasm. The adrenal gland is not present. An 8.5 cm segment of ureter is present and is essentially unremarkable. Sectioning of the renal parenchyma reveals a cyst measuring 1.5 cm in greatest dimension. Representative sections are submitted as follows: A1 ureter margin, A2 vascular margin, A3 pelvis and sinus, A4 cyst, A5-A6 sinus and mass, A7-A10 mass and capsule and soft tissue margin.

[page 2 of 2]
Patient ID #: [REDACTED]
DOB: [REDACTED] M
Date of Report:
Date of Procedure:
Date of Receipt:
Submitted by:
Location:

Lab and Collection

SURGICAL PATHOLOGY ([REDACTED]) on [REDACTED] - Lab and Collection Information

Result History

SURGICAL PATHOLOGY ([REDACTED]) on [REDACTED] - Order Result History Report.

Result Information

Result Date and Time	Status Final result	Provider Status Ordered
----------------------	------------------------	----------------------------

Status:

This result is currently not released to

[Display Full Result Report](#)

[Display Order Report](#)

Reviewer Initials	M6	10/3/13

Source: NCI Genomic Data Commons file 2d251759-6ea5-4d30-95e7-3ae7f6247e18 (TCGA-IA-A83W.10CCB12F-77E0-4100-A87A-0D36E5AF7F8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).